Surgical pathology report (de-identified scan), TCGA case TCGA-36-1569, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-1569-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

DOB/Gender:

Ordering Physician:

F

Final Diagnosis:

1. Omentum, excision: Omental tissue extensively invaded by high-grade papillary serous carcinoma with numerous psammoma bodies, tumor is present in lymphatic channels.
2. "Uterus, cervix, bilateral fallopian tubes and ovaries", total abdominal hysterectomy and bilateral salpingo-oophorectomy specimen showing:
- A. High-grade papillary serous carcinoma extensively replacing the left and right ovaries including surface involvement.
- B. Tumor envelopes the left fallopian tube.
- C. The right fallopian tube is negative for tumor.
- D. The endometrium is negative for tumor and shows predominantly weakly proliferative endometrium with focal areas of simple cystic hyperplasia.
- E. Several leiomyomata.
- F. Foci of adenomyosis.
- G. Cul-de-sac is negative for tumor.
- H. In the section labelled "anterior isthmus" tumor is present on the serosal aspect of the uterus.
3. Sigmoid serosa, biopsy: Fibrofatty tissue extensively invaded by high-grade papillary serous carcinoma.
4. Sigmoid mesentery, excision: Fibrofatty tissue extensively invaded by high-grade papillary serous carcinoma.

Clinical History as Provided by Submitting Physician:

Ca ovary

A. Omentum

B. Uterus, cervix, ovaries and fallopian tubes

C. Sigmoid serosa

D. Sigmoid mesentery

Specimens Received:

A: omentum

B: uterus + cervix + ovaries + fallopian tubes

C: sigmoid serosa

D: sigmoid mesentery

Gross Description:

Specimen is received in four containers each labelled with the patient's name.

Container "A" is labelled "omentum" and consists of an apron of greater omentum measuring 23.0 x 11.0 x 3.0 cm. The omentum is distorted by a firm nodule measuring 15.0 x 8.0 x 2.0 cm. On cross-section the nodule demonstrates a tan-white structure with areas of necrosis. Representative sections are submitted as "A1" through "A4".

Container "B" is labelled "uterus, cervix, bilateral fallopian tubes and ovaries" and consists of the same structures with a total weight of 79 g. The cervix

[page 2 of 2]
is amputated in the operation room at the level of the upper third of the endocervical canal is submitted separately in the same container. The uterus measures 3.5 cm in length, 3.5 cm side-by-side and 2.5 cm from anterior to posterior. The cervix measures 3.2 cm x 3.1 cm. The external surface of the uterus is covered with tan-white glistening serosa. The right fallopian tube measures 6.2 cm in length and 0.5 cm in diameter. On the external surface of the fallopian tube there are numerous thin-walled cysts with homogenous content. The right ovary measures 3.9 x 2.0 cm x 2.1 cm. On the external surface there is a papillary lesion measuring 1.5 cm in greatest dimension. The left fallopian tube measures 7.0 cm in length and 0.5 cm in diameter. The left ovary measures 2.0 cm x 1.5 x 1.3 cm. The external surface represents a papillary lesion. The mucosa of the cervix is tan-white, glistening and unremarkable. In the broad ligament adjacent to the anterior surface of the uterus there are three tan-white firm nodules measuring up to 1.1 cm in greatest dimension.

The bivalved uterus demonstrates unremarkable endocervical canal. The endometrium is even with a thickness of 0.2 cm except for one polyp over the right fundus measuring 0.5 x 0.4 cm. In the anterior myometrium there is one fibroid nodule measuring 0.6 cm in greatest dimension. In the posterior myometrium there are two fibroid nodules measuring 0.2 and 0.5 cm in diameter. At the fimbriated end of the right fallopian tube there is a firm tan-white nodule measuring 1.1 cm in greatest dimension. Cross-section of the right ovary reveals a cyst. The thickness of the cyst wall is 0.5 cm and there is a solid area measuring 1.6 x 1.5 cm. At the fimbriated end of the left fallopian tube there is a firm tan-white nodule measuring 1.3 in greatest dimension. Representative sections are submitted as follows:

- "B1" -anterior cervix
- "B2" -posterior cervix
- "B3" -cul-de-sac
- "B4" -anterior isthmus
- "B5" -posterior isthmus
- "B6-B7" -anterior endometrium
- "B8-B9" -posterior endometrium
- "B10" -right fallopian tube

- "B11-B12" -right ovary
- "B13" -left fallopian tube
- "B14" -left ovary
- "B15" -anterior peritoneal reflexion

Container "C" is labelled "sigmoid serosa" and consists of a fragment of serosa with numerous firm fibrous-like nodules measuring 7.5 x 3.0 x 1.1 cm. Representative sections are submitted as "C1" through "A3".

Container "D" is labelled "sigmoid mesentery" and consists of fragments of soft tissue measuring 2.4 x 1.1 x 0.6 cm. The specimen is submitted in toto in cassettes "D1" and "D2".

Source: NCI Genomic Data Commons file 0aae487b-a561-4506-8bb3-30b2c693a1cd (TCGA-36-1569.52192360-2ACE-401C-9642-B3D6F677362D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).